MMRF case MMRF_2477 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3280a484-e31c-4566-a111-b9aee0c80e89

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 485 days (1.3 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.4 years (22,414 days); ISS stage: III; Days to last known disease status: 485 days (1.3 years); Days to last follow up: 485 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 40 days; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 382 days (1.0 years); Days to treatment end: 485 days (1.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 485.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 3): M Protein 5.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 2.42 g/L; Immunoglobulin A 61.1 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 10.9 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.36 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.53 mmol/L; Albumin 29 g/L; Total Protein 9.2 g/dL; Glucose 5.28 mmol/L.
- Day 85: M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 4.14 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 9.98 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.88 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 4.84 mmol/L.
- Day 183: M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Hemoglobin 11.7 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.11 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 267: Hemoglobin 9.61 mmol/L; Leukocytes 4.8 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 7.4 g/dL; Glucose 4.07 mmol/L.
- Day 365: M Protein 3.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Hemoglobin 8.99 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.27 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.65 mmol/L; Albumin 33 g/L; Total Protein 9.7 g/dL; Glucose 4.35 mmol/L.

Other clinical attributes
- Day 0: Weight: 77 kg; Height: 158 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Leukemia.

Biospecimens (2 samples)
- Sample MMRF_2477_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2477_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
